Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A88S, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A88S-01A (Primary Tumor).

[page 1 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 2
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

History of dysphagia and reflux, Barium swallow that showed a stricture, multiple biopsies taken showed invasive squamous carcinoma, poorly differentiated. PET scan showed hyper metabolic distal esophagus. No evidence of frank metastasis. Clinical Diagnosis: Esophageal carcinoma. Operative Procedure/Tissue Submitted: Transhiatal esophagectomy, flexible esophagoscopy, pyloromyotomy, jejunostomy. Small bowel nodule.

PROCEDURE:

VERIFIED BY:

1. "Small bowel nodule (frozen section)." Received fresh for frozen section is a 1.0 cm soft pink tissue nodule.
1A. Frozen section control.

2. "Distal esophagus and proximal stomach." Received in formalin in a large container is a 14.2 cm segment of distal esophagus and proximal stomach with attached perigastric fat. There are staple lines at the proximal and distal margin.

Arising in the distal esophageal mucosa is a 3.8 x 3.2 cm near circumferential mass with ulceration. This firm area comes to within 0.5 cm of the esophagogastric junction. The cut surface through the centrally ulcerated mass is gray-tan to white with a maximum thickness of 0.7 cm, penetrating to the muscular wall and within 0.1 cm of the adventitia. No direct invasion to the gastric mucosa is readily seen.

Lymph node candidates are retrieved from the perigastric fat up to 2.4 cm in greatest dimension. The cut surface of the largest lymph node candidate is pink-brown and partly hemorrhagic.

Ink Code:
Green ink is applied to the adventitia.
Black ink on the gastric serosa.

Cassette Summary:
2A-C. Tumor with EG junction.
2D. Uninvolved EG junction.
2E. Eight whole lymph node candidates.
2F. Bisected lymph node candidate.
2G. Bisected lymph node candidate.
Fat retained.

3. "Cervical esophageal margin." Received in formalin in a small container is a 0.8 cm segment of esophagus that is stapled at one margin and opened at the opposing margin. The adventitia and submucosa are focally hemorrhagic, and the mucosa is unremarkable.

3A. Cervical esophageal margin.

ICD-O-3

Carcinoma, squamous cell NOS 807613
Site Distal third of esophagus C15.5
QID 11/12/13

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 3
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

FROZEN SECTION REPORT

1. Negative for malignancy.

I, _____ have reviewed and interpreted the frozen section material at the time it was requested.

Frozen section diagnosis is confirmed.

PROCEDURE:

VERIFIED BY:

ESOPHAGUS, GASTROESOPHAGEAL JUNCTION, INCLUDING CARDIA,
CARCINOMA (RESECTION SPECIMENS):
=====

LOCATION: Lower esophagus.

SIZE: 3.8 x 3.2 x 0.7 cm.

TYPE OF CARCINOMA: Squamous cell carcinoma, typical.

GRADE: Moderately.

DEPTH OF INVASION: Adventitia.

NUMBER OF POSITIVE LYMPH NODES / TOTAL NUMBER OF NODES EXAMINED: 0/8.

DISTANT METASTASIS: Unknown.

RESECTION MARGIN INVOLVED: No.

pT3 NO MX

PROCEDURE:

VERIFIED BY:

1. "Small bowel nodule", excision: Accessory spleen. Negative for malignancy.

2-3. Distal esophagus and proximal stomach, transhiatal esophagectomy, and separately submitted cervical esophageal margin, excision: Moderately-differentiated, invasive squamous cell carcinoma of the esophagus; margins free. Eight lymph nodes negative for carcinoma (0/8). Incidental accessory spleen.

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 4
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC

I, , the signing staff pathologist, have personally
examined and interpreted the slides from this case.

Code:

Code:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Unl/Synchronous Malignancy Noted		

Source: NCI Genomic Data Commons file 2bd635ea-898d-4452-ac19-f8d995b62a9f (TCGA-L5-A88S.DA04E7E4-BF19-40E2-9532-7D83FB4FF763.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).